Gene-level copy-number profile of tumor specimen TCGA-CV-5444-01A from TCGA case TCGA-CV-5444, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.8 years (23,650 days).
Specimen TCGA-CV-5444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e9bf7aed-fb96-45ab-aef5-5606bc82edaa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5444-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe9269df-45c8-4598-b1fe-bcc7f0311eca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 15,403; copy number 2: 25,262; copy number 3: 14,139; copy number 4: 3,775; copy number 5: 1,202; copy number 7: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5444-01A-02D-1510-01): tumor purity 0.27, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:168,356,735–168,928,457, 8 genes (within-gene range 0–1): DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1.
- chr4:186,189,032–186,726,722, 12 genes: FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1.
- chr16:53,981,229–53,994,454, 2 genes: AC007496.2, AC007496.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,215 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:33,290,512–36,487,548, 162 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr9:91,563,091–112,669,397, 402 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:112,878,920–138,203,325, 651 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
